Surgical pathology report (de-identified scan), TCGA case TCGA-DJ-A3VA, project TCGA-THCA (Thyroid Carcinoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DJ-A3VA-01A (Primary Tumor).

[page 1 of 3]
Reviewer Initials	RB	Dr. e Reviewed: 4/9/12

Head & Neck
Head And Neck

Date of Procedure:
Date of Receipt:
Date of Report:
Account #:
Billing Type:
Additional Copy to:

Clinical Diagnosis & History:

With papillary thyroid carcinoma and neck nodes.

Specimens Submitted:

- 1: Left level two lymph node cervical (fs)
- 2: Left level three lymph node cervical (fs)
- 3: Total thyroidectomy
- 4: Pre-tracheal lymph node and left paratracheal lymph nodes

DIAGNOSIS:

1. Left level two lymph node cervical (fs); excision:
- One benign lymph node
2. Left level three lymph node cervical (fs); excision:
- Two benign lymph nodes
3. Total thyroidectomy:
Part # 3
Tumor Type:
Papillary carcinoma, classical type

Histologic Grade:
Well differentiated

Mitotic Activity:
Not identified

Tumor Necrosis:
Not identified

Tumor Location:
Left lobe

Tumor Size:
Greatest diameter is 2.0 cm.

Tumor Encapsulation:
Completely surrounded

Capsular Invasion:
Focal invasion
Blood Vessel Invasion:
Not identified

Extrathyroid Extension:
Not identified

ICD-O-3

Carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS

C73.9 5-2-12
RD

[page 2 of 3]
Surgical Margins:

Free of tumor

Tumor Multicentricity:

Two separate foci of papillary carcinoma tall cell variant in left lobe and isthmus (0.5 and 0.2 cm)

Non-Neoplastic Thyroid:

Exhibits chronic lymphocytic thyroiditis consistent with Hashimoto's thyroiditis

Parathyroid Glands:

Not identified

Lymph Nodes:

Number of nodes examined: 6

Six benign lymph nodes.

4. Pre-tracheal lymph node and left paratracheal lymph nodes; excision:
- Micrometastatic papillary thyroid carcinoma to one of nineteen lymph nodes (1/19). The metastatic node is 1.3 cm in greatest size. The metastatic tumor measures <0.1 cm in aggregate. No extra-nodal extension seen.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

- 1) The specimen is received fresh for frozen section consultation labeled, "Left level two lymph node, cervical" and consists of one tan pink lymph node measuring 1.6 cm in greatest dimension and is bisected. The lymph node is entirely submitted for frozen section.

Summary of sections:

FSC - frozen section control

- 2). The specimen is received fresh for frozen section consultation labeled, "Left level three lymph node cervical" and consists of two tan pink lymph nodes measuring 1.8 cm and 1.1 cm in greatest dimension. Both lymph nodes are bisected and entirely submitted for frozen section.

Summary of sections:

FSCA - frozen section control, larger lymph node bisected

FSCB - frozen section control, smaller lymph node bisected

- 3). The specimen is received fresh and placed in formalin, labeled "total thyroidectomy" and consists of a previously sectioned thyroid weighing 22.63 g. The right lobe measures 4.5 x 2 x 1 cm, the left lobe measures 3.8 x 3 x 2 cm and the isthmus measures 1.8 x 1 x 0.4 cm. The external surface is covered by a thin fibrous capsule. The posterior surface of the specimen is inked black, and the anterior is inked blue. Sectioning reveals 2 x 1.8 x 1.5 cm partially cystic mass, located in the left lobe. Sections through the remaining tissue are unremarkable. Sectioning the right lobe reveals multinodular white-tan lesions (0.1 to 0.3 cm). Representative sections of the specimen are submitted for , and a photograph has been taken. The remaining tissue is serially sectioned and entirely submitted.

Summary of sections:

N - nodule, left lobe

LL - left lobe

RL - right lobe

IS - isthmus

[page 3 of 3]
4). The specimen is received in formalin, labeled "pretracheal lymph node and left paratracheal lymph nodes" and consists of multiple pink tan firm lymph nodes ranging from 0.1 to 1.5 cm in greatest dimension. All identified lymph nodes are submitted.

Summary of sections:

LN - lymph nodes

BLN - bisected lymph node

Summary of Sections:

Part 1: Left level two lymph node cervical (fs)

Block	Sect. Site	PCs
1	fsc	2

Part 2: Left level three lymph node cervical (fs)

Block	Sect. Site	PCs
1	fsca	2
1	fscb	2

Part 3: Total thyroidectomy

Block	Sect. Site	PCs
8	N	8
1	IS	2
2	LL	2
8	RL	8

Part 4: Pre-tracheal lymph node and left paratracheal lymph nodes

Block	Sect. Site	PCs
1	BLN	2
4	LN	18

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. Frozen Section Diagnosis: Left level two lymph node cervical (fs): Benign
Permanent Diagnosis: Same
2. Frozen Section Diagnosis: Left level three lymph node cervical (fs): Benign ()
Permanent Diagnosis: Same

Source: NCI Genomic Data Commons file 377fc6dd-a51f-45fb-8111-2b1007dfb495 (TCGA-DJ-A3VA.A92EF72D-7397-4DB3-9DBF-CCADD9DA8DE2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).